Somatic mutation profile of tumor specimen MP2PRT-PAULDZ-TMP1-A (aliquot MP2PRT-PAULDZ-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAULDZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.2 years (2,995 days).
Specimen MP2PRT-PAULDZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c49fdf5f-664d-4555-9b1c-0504eb08fe41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULDZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULDZ-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52e7bb99-48a0-4f95-8d5a-8ac65a58cca0

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 88/349 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CATSPERD | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 119/491 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1271959067; called by muse, mutect2, varscan2
- CRTAC1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 83/521 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs749734744; called by muse, mutect2, varscan2
- FBXO44 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1368802381, COSV52355851; called by muse, mutect2, varscan2
- KPRP | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 63/678 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765434263, COSV64220950; called by muse, mutect2
- NPC1L1 | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 134/478 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs371572587; called by muse, varscan2
- PHF24 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 69/640 reads (11%) | catalogued as rs1055523080, COSV54273682; called by muse, mutect2, varscan2
- SLC45A3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 62/713 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs540456576, COSV65655604; called by muse, mutect2
- C2orf16 | c.1861G>T p.A621S | Missense Mutation (SNP) | VAF 56/470 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PPP4R3C | c.1404A>T p.K468N | Missense Mutation (SNP) | VAF 83/432 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PTPRQ | c.2036T>A p.M679K (on ENST00000616559; = p.M637K on NM_001145026.2) | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2
- PTPRN2 | c.1821G>A p.A607= | Silent (SNP) | VAF 56/471 reads (12%) | catalogued as rs374727856; called by muse, mutect2, varscan2
- SART3 | c.162G>T p.A54= | Silent (SNP) | VAF 157/565 reads (28%) | called by muse, mutect2, varscan2
- TSEN54 | c.1503C>T p.I501= | Silent (SNP) | VAF 116/616 reads (19%) | called by muse, mutect2, varscan2
- ZBTB41 | c.12G>A p.R4= | Silent (SNP) | VAF 54/194 reads (28%) | called by muse, mutect2, varscan2
- TRDJ1 | chr14:22449125 ins GAAA | 5'Flank (INS) | VAF 72/366 reads (20%) | called by mutect2, pindel, varscan2
